Surgical pathology report (de-identified scan), TCGA case TCGA-DU-8163, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-8163-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

Patient Name: [REDACTED]

Med: Rec.: [REDACTED]

DOB: [REDACTED]

Client: [REDACTED]

Accession #: [REDACTED]

Phone Number: [REDACTED]

Gender: M

Location: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

CLINICAL HISTORY

[REDACTED] man experienced recent onset seizures, and during work up was found to have a 4 x 3 cm, nonenhancing lesion in the left middle temporal lobe. Tumor was partially resected, and in follow up imaging there are focal areas of enhancement.

OPERATIVE DIAGNOSES

Left temporal glioma

Operation/Specimen: A: Brain, biopsy#1

B: Brain, biopsy#2

C: Brain, residual posterior superior flair, biopsy

PATHOLOGICAL DIAGNOSIS:

A, B, C. Brain, sites not specified, excisions: Mixed oligoastrocytoma, with focal anaplastic features (WHO grade III). See Microscopy Description and Comment.

COMMENT

Parts A, B, and C are portions of cerebrum that are sparsely to moderately, and diffusely infiltrated by a glial neoplastic proliferation. The neoplastic cells are mostly naked, round to ovoid naked nuclei with little pleomorphism. Focally, there are mitotic figures up to seven / ten high power fields, and the MIB-1 proliferation index is moderately elevated to about 10% in the more active areas. There are occasionally vessels with endothelial hyperplasia, and there are a couple of zones with microvascular cellular proliferation.

[page 2 of 5]
There is no tumor necrosis.

These findings are interpreted as those of a mixed oligoastrocytoma that focally is undergoing anaplastic transformation (WHO III). Molecular testing may better characterize the tumor.

In part B there is also a portion of the cavity of the previous surgery; it contains inflamed granulation tissue and fragments of surgical hemostatic material. Focally, the brain tissue surrounding the cavity has infiltrating atypical cells consistent with neoplasia.

Parts A and C are moderately infiltrated by the neoplastic proliferation.

Parts A and C contain a few vessels with microvascular cellular proliferation.

=====

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S548, D1S552, D19S412, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block. DNA extracted from a corresponding blood specimen was used as a normal reference control.

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

[page 3 of 5]
nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[REDACTED]

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

[page 4 of 5]
assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

B.

"Biopsy #2: Diffusely infiltrating glioma, with abnormal vessels (transforming?). [REDACTED] Touch preparation smears performed at [REDACTED]

[REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

"Biopsy # 1." received fresh, three fragments, 0.8 x 0.8 x 0.2 cm in aggregate. Semi firm, tannish-white, glistening. A1

B.

"Biopsy # 2," received fresh, two fragments, 1.7 x 1.4 x 0.6 cm in aggregate.

Semi firm, tannish-white, glistening. Serially sectioned, B1 and B2.A.

C.Brain, residual posterior superior flair, biopsy: CONTAINER LABEL: residual

posterior superior flair.

FIXATIVE: Formalin. NO. PIECES: 1 and fleck. SIZE/VOL: 3.5x1.5x0.7 cm.; 1.06

grams CASSETTES: 1, 2NS.

[REDACTED]

[page 5 of 5]
[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a moderate gliofibrillary background, and focally numerous mini gemistocytes. A large majority of neoplastic cells strongly over express the p53 protein. With the MIB-1 there is a proliferation index of about 10% in the more active areas. The CD34 depicts focal microvascular cellular proliferation.

ICD-9(s):
191.2 191.2

[REDACTED]

Histo Data

Part A: Brain, biopsy#1

Taken:	Received:	Block	Ordered	Comment
[REDACTED]	[REDACTED]	1	[REDACTED]	
CD34-DA x 1		1	[REDACTED]	
mGFAP-DA x 1		1	[REDACTED]	
H/E x 1		1	[REDACTED]	
LOH-curles x 1		1	[REDACTED]	1p, 19q, please.
MGMT-curles x 1		1	[REDACTED]	
MIB1-DA x 1		1	[REDACTED]	
P53DO7 x 1		1	[REDACTED]	
Rct 1 H/E x 1		1	[REDACTED]	blocks pulled

Part B: Brain, biopsy#2

Taken:	Received:	Block	Ordered	Comment
[REDACTED]	[REDACTED]	1	[REDACTED]	
H/E x 1		1	[REDACTED]	
Rct 1 H/E x 1		1	[REDACTED]	blocks pulled
TPS H/E x 1		1	[REDACTED]	
H/E x 1		2	[REDACTED]	
Rct 1 H/E x 1		2	[REDACTED]	blocks pulled

Part C: Brain, residual posterior superior flair, biopsy

Taken:	Received:	Block	Ordered	Comment
Stain, [REDACTED]	[REDACTED]	1	[REDACTED]	
H/E x 1		1	[REDACTED]	
Rct 1 H/E x 1		1	[REDACTED]	blocks pulled
H/E x 1		2	[REDACTED]	
Rct 1 H/E x 1		2	[REDACTED]	blocks pulled

*** End of Report ***

Source: NCI Genomic Data Commons file 4ead95c1-8758-449a-ac86-810d8c9afed7 (TCGA-DU-8163.7C9B671F-E8F9-4B12-B497-6BC252FE9B15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).